TCGA case TCGA-DD-A4NN — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b96b7620-5506-4def-aff2-5e888eaf3ea5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Dead; Days to death: 899 days (2.5 years).

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 56.3 years (20,548 days); Year of diagnosis: 2004; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 899 days (2.5 years); Child pugh classification: A; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 56.7 years (20,714 days); Days to diagnosis: 166 days; Prior treatment: Yes.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 166 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 166 days.
- Days to follow up: 899 days (2.5 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Platelets 307 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Alpha Fetoprotein 4223 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.2].
- Prothrombin Time 8.8 Seconds [Blood test normal range lower: 8; Blood test normal range upper: 12].
- Total Bilirubin 0.5 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Albumin 4.3 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 59 kg; Height: 163 cm; BMI: 22.2.

Family history
- Relatives with cancer history count: 1.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-A4NN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 240 mg.
  Slide TCGA-DD-A4NN-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DD-A4NN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-A4NN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-DD-A4NN-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 200 mg.
  Slide TCGA-DD-A4NN-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Multiple.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 899 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 899 days; disease-free interval: event (new tumor event after initially disease-free), 166 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 166 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-A4NN-01A-11D-A28W-01): tumor purity 0.92, ploidy 2.03, whole-genome doublings 0.
